Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JC, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JC-01A (Primary Tumor).

[page 1 of 2]
Requesting Doctor's Information:

ICD-0-3

Carcinoma, adrenal cortical 837613

Site: Adrenal gland
cortex C74.0

QD 1/20/13

SPECIMEN TYPE: Adrenal Mass

CLINICAL NOTES:

L) adrenal tumour -> gynaecomastia.

MACROSCOPIC:

"Left adrenal tumour." The specimen consists of a lobulated, roughly ovoid mass, 135 x 100 x 90mm, weighing 754g. The specimen has been previously incised prior to receipt over a length of 45mm. The mass is lobulated and surrounded by a thin layer of adipose tissue. On sectioning, lobules of tan tissue are separated by fine fibrous bands. Areas of haemorrhage and necrosis are identified. Most of the tumour is light brown/tan. Small amounts of residual adrenal gland parenchyma are present at the peripheries. Representative tissue embedded in six blocks.

MICROSCOPIC:

The adrenal tumour is a high grade adrenal cortical carcinoma. The tumour is variable in its architecture, including diffuse sheets, areas of glandular, papillary and trabeculae formation, and regions where the cells are more insular in their arrangement. There are occasional well differentiated areas where the tumour vaguely resembles normal adrenal cortical parenchyma. The cells have abundant granular eosinophilic cytoplasm with clear cell areas. Nuclear pleomorphism is variable and overall moderate. There is a rich vascular background with large areas of haemorrhage and necrosis. Mitoses are numerous, including atypical forms, up to 24/50 hpf.

There is prominent vascular space permeation within capsular vessels, showing formation of tumour thrombi.

A thick fibrous capsule surrounds the tumour and local resection appears complete.

A rim of atrophic adrenal cortex is seen at one end.

SUMMARY:

Left adrenal mass:

High grade adrenal cortical carcinoma, with prominent vascular space permeation.

Local excision appears complete.

T-93000 M-80103

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

[page 2 of 2]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal Mass

REPORTING PATHOLOGIST:

(Electronic Signature)

HISTOPATHOLOGY

ANATOMICAL PATHOLOGY

Primary Turnout Site Discrepancy		☒

Source: NCI Genomic Data Commons file 610f25ed-09aa-4f29-ad65-f9b9d37eec34 (TCGA-OR-A5JC.328B8F7A-8CEC-4670-A83F-B16AF53E74CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).